Somatic mutation profile of tumor specimen TCGA-ET-A3DP-01A (aliquot TCGA-ET-A3DP-01A-11D-A21A-08) from TCGA case TCGA-ET-A3DP, project TCGA-THCA (Thyroid Carcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland; AJCC pathologic stage: Stage I; Age at diagnosis: 43.5 years (15,876 days).
Specimen TCGA-ET-A3DP-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) b0a5676e-c0b9-47c2-82b8-de8df6cf7da6.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-ET-A3DP-11A (Solid Tissue Normal), aliquot TCGA-ET-A3DP-11A-22D-A21A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/780029db-e6ce-4be3-abd2-e6e2e115affc

The open-access MAF lists 10 somatic variants for this specimen: 8 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 7, Silent 2, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BRAF | c.1919T>A p.V640E (on ENST00000288602 / NM_001374244.1; = p.V600E on NM_004333.6 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 18/41 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (0.955); catalogued as rs113488022, CM112509, COSV56056643, COSV56065204, COSV56080151; ClinVar: pathogenic / likely pathogenic / other / drug response; called by muse, mutect2, varscan2
- COL11A2 | c.3160G>A p.G1054S (on ENST00000341947 / NM_080680.3; = p.G947S on NM_080679.2) | Missense Mutation (SNP) | VAF 8/23 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59493474; called by muse, mutect2, varscan2
- FBXL20 | c.817C>T p.P273S | Missense Mutation (SNP) | VAF 25/84 reads (30%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as rs1382893802, COSV52896258; called by muse, mutect2, varscan2
- LIMD1 | c.34A>T p.S12C | Missense Mutation (SNP) | VAF 13/47 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56265865; called by muse, mutect2, varscan2
- MACC1 | c.1337T>A p.V446E | Missense Mutation (SNP) | VAF 2/20 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100255889; called by muse, mutect2
- PCLO | c.5770A>G p.K1924E | Missense Mutation (SNP) | VAF 5/9 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.797); catalogued as rs774667224, COSV61615619; called by muse, mutect2
- SPAG9 | c.2746G>T p.E916* (on ENST00000262013 / NM_001130528.3; = p.E902* on NM_003971.6) | Nonsense Mutation (SNP) | VAF 4/46 reads (9%) | catalogued as COSV56231056; called by muse, mutect2, varscan2
- MACC1 | c.1336G>A p.V446I | Missense Mutation (SNP) | VAF 2/18 reads (11%) | SIFT tolerated (0.19); PolyPhen benign (0.293); called by muse, mutect2
- RPL36A | c.312C>A p.I104= | Silent (SNP) | VAF 12/39 reads (31%) | catalogued as rs782719912, COSV54508081; called by muse, mutect2, varscan2
- TSSK4 | c.525T>C p.S175= | Silent (SNP) | VAF 11/179 reads (6%) | catalogued as COSV55302371; called by muse, mutect2
